Somatic mutation profile of tumor specimen MP2PRT-PAPHFA-TMP1-A (aliquot MP2PRT-PAPHFA-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PAPHFA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,983 days).
Specimen MP2PRT-PAPHFA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46cef438-b4f6-4d87-a343-3c61928e5a85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPHFA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPHFA-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a9fb928-05a5-4119-ab86-badae1986168

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 60/330 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 74/349 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 62/591 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs781092819; called by muse, mutect2, varscan2
- CAPN6 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 135/1064 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.666); catalogued as rs1360970370, COSV60694506; called by muse, mutect2, varscan2
- CNTN5 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 118/391 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs200403626; called by muse, mutect2, varscan2
- HIC1 | c.1130C>T p.P377L (on ENST00000322941 / NM_001098202.1; = p.P358L on NM_006497.4) | Missense Mutation (SNP) | VAF 154/545 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs1211679088; called by muse, mutect2, varscan2
- PICK1 | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 142/349 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV63659570; called by muse, mutect2, varscan2
- SHPK | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 88/495 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754993710; called by muse, mutect2, varscan2
- SLC2A6 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 269/806 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.27); catalogued as rs1205316082; called by muse, varscan2
- LRRC8D | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 88/359 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MBNL1 | c.445A>T p.I149F | Missense Mutation (SNP) | VAF 14/466 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2
- NHS | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 266/1084 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); called by muse, varscan2
- PENK | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 192/425 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- RPS6KA3 | c.185A>T p.K62M | Missense Mutation (SNP) | VAF 115/522 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- CNTNAP3 | c.2448C>T p.D816= | Silent (SNP) | VAF 63/470 reads (13%) | catalogued as rs780612729, COSV52668090; called by muse, mutect2, varscan2
- GRM4 | c.759G>A p.S253= | Silent (SNP) | VAF 127/682 reads (19%) | catalogued as rs1416728164, COSV65214063; called by muse, mutect2, varscan2
- HCN1 | c.12C>T p.G4= | Silent (SNP) | VAF 115/254 reads (45%) | catalogued as COSV100303197; called by muse, mutect2, varscan2
- LAGE3 | c.21C>T p.D7= | Silent (SNP) | VAF 46/1724 reads (3%) | catalogued as rs1389007669; called by muse, mutect2
